Somatic mutation profile of tumor specimen TCGA-5N-A9KM-01A (aliquot TCGA-5N-A9KM-01A-11D-A42E-08) from TCGA case TCGA-5N-A9KM, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 73.7 years (26,906 days).
Specimen TCGA-5N-A9KM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 240eb695-bb3e-4a0a-976e-0d26f602bba3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-5N-A9KM-10A (Blood Derived Normal), aliquot TCGA-5N-A9KM-10A-01D-A42H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/86e9832d-8abe-43a6-b950-7408dc7dee80

The open-access MAF lists 246 somatic variants for this specimen: 166 protein-altering or splice-affecting, 72 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 141, Silent 72, Nonsense Mutation 11, Frame Shift Del 5, 3'UTR 3, Frame Shift Ins 3, Splice Site 3, Intron 2, 3'Flank 2, In Frame Del 1, RNA 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TSC1 | c.1264-1G>A p.X422_splice | Splice Site (SNP) | VAF 7/18 reads (39%) | catalogued as rs1554816432, COSV100051608, COSV53768250; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AARS2 | c.1009G>T p.D337Y | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV55117545; called by muse, mutect2, varscan2
- ADAMTS18 | c.1609G>T p.V537L | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV51423168; called by muse, mutect2, varscan2
- ADARB2 | c.941G>A p.G314D | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.76); catalogued as COSV101187356; called by muse, mutect2, varscan2
- ADGRL3 | c.1663G>A p.A555T (on ENST00000506720 / NM_001322402.2; = p.A487T on NM_015236.6) | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.44); PolyPhen benign (0.248); catalogued as COSV72231971; called by muse, mutect2, varscan2
- AICDA | c.511C>A p.R171S | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.605); catalogued as COSV57563722, COSV57563879; called by muse, mutect2, varscan2
- ALOX5 | c.1219A>G p.I407V | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.07); catalogued as COSV65554401; called by muse, mutect2, varscan2
- APBA2 | c.1198G>A p.A400T | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs755317945, COSV101258218; called by muse, mutect2
- APOA4 | c.431C>T p.T144I | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as rs755648505, COSV63361175; called by muse, mutect2, varscan2
- ARHGEF6 | c.2111A>G p.N704S | Missense Mutation (SNP) | VAF 44/142 reads (31%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as COSV51695985; called by muse, mutect2, varscan2
- ARID4A | c.1255G>C p.E419Q | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs752523201, COSV62163318, COSV62164088; called by muse, mutect2, varscan2
- ATM | c.8918G>C p.R2973T | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV53775080; called by muse, mutect2, varscan2
- BUB1 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 44/161 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV57067327; called by muse, mutect2, varscan2
- C10orf88 | c.335G>T p.R112M | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64404446; called by muse, mutect2, varscan2
- C1QTNF1 | c.386G>A p.G129E | Missense Mutation (SNP) | VAF 40/56 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59264441; called by muse, mutect2, varscan2
- CACNA1H | c.6791C>T p.P2264L | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.251); catalogued as COSV52358430; called by mutect2, varscan2
- CALD1 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV100724597; called by muse, varscan2
- CARMIL1 | c.2774A>G p.H925R | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.925); catalogued as COSV61522793; called by muse, mutect2
- CBLIF | c.675T>G p.S225R | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57238748, COSV57240423; called by muse, mutect2, varscan2
- CCNB3 | c.3028G>A p.E1010K | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs868979733, COSV52079747; called by muse, mutect2, varscan2
- CD1E | c.147C>A p.S49R | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63769950; called by muse, mutect2, varscan2
- CDH10 | c.1510G>T p.G504W | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52597939; called by muse, mutect2, varscan2
- CLEC4A | c.551A>G p.Y184C | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774305756, COSV57562886; called by muse, mutect2, varscan2
- CLSTN3 | c.2209G>A p.E737K | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV56940411; called by muse, mutect2, varscan2
- COL9A1 | c.911C>T p.P304L | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1394702419, COSV57893213; called by muse, mutect2, varscan2
- CRYBB1 | c.248T>C p.L83P | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as rs1335934959, COSV53234768; called by muse, mutect2, varscan2
- CSN3 | c.179C>A p.T60N | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.113); catalogued as rs761442017, COSV59243829; called by muse, mutect2, varscan2
- CTDSPL2 | c.1129G>A p.E377K | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV52946257; called by muse, mutect2, varscan2
- DENND4A | c.3481A>C p.T1161P | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.767); catalogued as COSV101475444; called by muse, mutect2, varscan2
- DICER1 | c.5024A>T p.Y1675F | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as COSV58628249; called by muse, mutect2, varscan2
- DIDO1 | c.4211G>A p.R1404Q | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV56627215; called by muse, mutect2, varscan2
- DMD | c.1745T>A p.V582E | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as rs1556809842, COSV55901255; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAI1 | c.766A>G p.K256E | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as COSV54284836; called by muse, mutect2, varscan2
- DNMBP | c.3634G>A p.G1212S | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as COSV60633132; called by muse, mutect2, varscan2
- DOCK11 | c.1816G>A p.V606M | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as rs1201474821, COSV52247751; called by muse, mutect2, varscan2
- DPP4 | c.668dup p.L223Ffs*7 | Frame Shift Ins (INS) | VAF 26/54 reads (48%) | catalogued as rs1299375730; called by mutect2, pindel, varscan2
- ELF3 | c.690_691insAA p.G231Kfs*24 | Frame Shift Ins (INS) | VAF 10/38 reads (26%) | catalogued as COSV62840429; called by mutect2, pindel, varscan2
- ELOA2 | c.1543T>C p.Y515H | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55308673; called by muse, mutect2, varscan2
- ENPP3 | c.530G>A p.W177* | Nonsense Mutation (SNP) | VAF 16/43 reads (37%) | catalogued as COSV100718125; called by muse, mutect2, varscan2
- EPHA2 | c.2159del p.L720Rfs*8 | Frame Shift Del (DEL) | VAF 59/112 reads (53%) | catalogued as COSV64454735; called by mutect2, pindel, varscan2
- FYB2 | c.1598A>G p.K533R | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.575); catalogued as COSV58589362; called by muse, mutect2, varscan2
- GATA1 | c.920G>T p.R307L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1557020556, COSV64963548; called by muse, mutect2, varscan2
- GBP5 | c.1223T>C p.L408S | Missense Mutation (SNP) | VAF 56/173 reads (32%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV58594342; called by muse, mutect2, varscan2
- GDI1 | c.1302G>A p.M434I | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as COSV50133125; called by muse, mutect2, varscan2
- GLA | c.952G>T p.A318S | Missense Mutation (SNP) | VAF 49/136 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.174); catalogued as CD123321, COSV54509366, COSV54510581; called by muse, mutect2, varscan2
- GLRA2 | c.916G>T p.A306S | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.983); catalogued as COSV54343460, COSV54347672; called by muse, mutect2, varscan2
- GLUD2 | c.470G>C p.S157T | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV60153095; called by muse, mutect2, varscan2
- GNA13 | c.598A>G p.R200G | Missense Mutation (SNP) | VAF 30/40 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV71474990; called by muse, mutect2, varscan2
- GREB1 | c.2236G>A p.A746T | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.935); catalogued as COSV52196446; called by muse, mutect2, varscan2
- GRHL2 | c.401C>T p.S134F | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.025); catalogued as COSV52554933; called by muse, mutect2, varscan2
- GRIA1 | c.1991T>A p.L664Q | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53624744; called by muse, mutect2
- GRID2 | c.2129G>A p.R710Q | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs760655946, COSV56184633; called by muse, mutect2, varscan2
- HLCS | c.673A>G p.I225V | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs147107058; called by muse, mutect2, varscan2
- HSPA4L | c.1456A>G p.I486V | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV56548657; called by muse, mutect2, varscan2
- HUWE1 | c.10132C>T p.Q3378* | Nonsense Mutation (SNP) | VAF 15/31 reads (48%) | catalogued as rs1556924997, COSV99474346; called by muse, mutect2, varscan2
- IBSP | c.257A>G p.N86S | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.78); PolyPhen probably damaging (0.997); catalogued as COSV56897354; called by muse, mutect2, varscan2
- IKBKE | c.1514T>C p.V505A | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV65627037; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1894G>A p.V632I | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs1285357262, COSV56301315; called by muse, mutect2, varscan2
- IL4I1 | c.1610C>T p.P537L | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.04); catalogued as rs1310643323, COSV55581311; called by muse, mutect2, varscan2
- INCENP | c.527G>T p.R176L | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.245); catalogued as rs777641583, COSV53913910, COSV53921130; called by muse, mutect2, varscan2
- IPO7 | c.3094G>C p.G1032R | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV65687079; called by muse, mutect2, varscan2
- IRX1 | c.1351C>T p.Q451* | Nonsense Mutation (SNP) | VAF 14/42 reads (33%) | catalogued as COSV100116824; called by muse, mutect2, varscan2
- KDM5B | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.018); catalogued as rs755173272, COSV52512943; called by muse, mutect2, varscan2
- KIAA1586 | c.1894G>C p.D632H | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.77); catalogued as rs778598351, COSV66057459; called by muse, mutect2, varscan2
- KIF17 | c.1588T>C p.S530P | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.726); catalogued as COSV56122498; called by muse, mutect2, varscan2
- KLHL4 | c.1382C>A p.T461N | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.78); PolyPhen benign (0.02); catalogued as COSV64147948; called by muse, mutect2, varscan2
- KRTAP21-1 | c.59A>G p.Y20C | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV58646464, COSV58646992; called by muse, mutect2, varscan2
- LAMA4 | c.4924G>A p.E1642K (on ENST00000230538 / NM_001105206.3; = p.E1635K on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57904974, COSV57905430; called by muse, mutect2, varscan2
- LGR6 | c.280G>T p.E94* (on ENST00000367278 / NM_001017403.1; = p.E42* on NM_021636.3) | Nonsense Mutation (SNP) | VAF 25/81 reads (31%) | catalogued as COSV99707940; called by muse, mutect2, varscan2
- LRRK2 | c.3932T>C p.I1311T | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.026); catalogued as rs1042763240, COSV54147105; called by muse, mutect2, varscan2
- LRRTM4 | c.1107A>T p.E369D | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.48); PolyPhen benign (0.006); catalogued as rs1337742890, COSV69142329; called by muse, mutect2, varscan2
- MAS1 | c.455T>G p.V152G | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV53120614, COSV53122308; called by muse, mutect2, varscan2
- MERTK | c.2659G>C p.G887R | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV54935871; called by muse, mutect2, varscan2
- MFSD6 | c.731C>G p.S244* | Nonsense Mutation (SNP) | VAF 16/73 reads (22%) | catalogued as rs766973631, COSV99854978; called by muse, mutect2, varscan2
- MID2 | c.720G>T p.K240N | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.652); catalogued as COSV53314318; called by muse, mutect2, varscan2
- MOV10L1 | c.2384G>A p.R795Q | Missense Mutation (SNP) | VAF 81/194 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs779178382, COSV53179337; called by muse, mutect2, varscan2
- MPZL1 | c.599A>T p.Y200F | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100850412; called by muse, mutect2, varscan2
- MS4A1 | c.772A>G p.N258D | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV61943058; called by muse, mutect2, varscan2
- MUC16 | c.37004A>G p.Y12335C | Missense Mutation (SNP) | VAF 49/95 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.279); catalogued as COSV67494566; called by muse, mutect2, varscan2
- MYCBP2 | c.11339A>G p.K3780R (on ENST00000357337; = p.K3818R on NM_015057.5) | Missense Mutation (SNP) | VAF 58/164 reads (35%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.528); catalogued as COSV62039146; called by muse, mutect2, varscan2
- MYO10 | c.868A>T p.N290Y | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as COSV72454758; called by muse, mutect2, varscan2
- MYO15A | c.270G>T p.M90I | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT deleterious (0.02); PolyPhen benign (0.229); catalogued as COSV52752286, COSV52766204; called by muse, mutect2, varscan2
- MYO9A | c.3148C>T p.Q1050* | Nonsense Mutation (SNP) | VAF 13/38 reads (34%) | catalogued as rs1325580071, COSV100614376; called by muse, mutect2, varscan2
- NAT8L | c.555G>A p.W185* | Nonsense Mutation (SNP) | VAF 20/59 reads (34%) | catalogued as COSV100527098; called by muse, mutect2, varscan2
- NCKAP1 | c.1881+1G>A p.X627_splice | Splice Site (SNP) | VAF 27/98 reads (28%) | catalogued as rs1404715168, COSV62943723; called by muse, mutect2, varscan2
- NLGN4X | c.800A>G p.H267R | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV52036658; called by muse, mutect2, varscan2
- NONO | c.419G>T p.R140L | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as COSV52138972, COSV52140337; called by muse, mutect2, varscan2
- NPR1 | c.2353G>T p.A785S | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.304); catalogued as rs1019001741, COSV64118137; called by muse, mutect2, varscan2
- NR2F2 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1165407301, COSV67684151; called by muse, mutect2, varscan2
- NRCAM | c.2654A>G p.Y885C (on ENST00000379028 / NM_001371124.1; = p.Y869C on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs779010001, COSV61049154; called by muse, mutect2, varscan2
- NUDT9 | c.59C>G p.A20G | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.102); catalogued as COSV56197964; called by muse, mutect2, varscan2
- NYNRIN | c.4858G>T p.E1620* | Nonsense Mutation (SNP) | VAF 8/23 reads (35%) | catalogued as COSV101230709, COSV66842952; called by muse, mutect2, varscan2
- OR10J3 | c.926del p.N309Tfs*5 | Frame Shift Del (DEL) | VAF 25/81 reads (31%) | catalogued as rs779717612; called by mutect2, pindel, varscan2
- OR10J5 | c.277T>C p.S93P | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV58387776; called by muse, mutect2, varscan2
- OR12D2 | c.142A>G p.I48V | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.011); catalogued as rs924555034, COSV65830367; called by muse, mutect2, varscan2
- OR4Q3 | c.851A>G p.Y284C | Missense Mutation (SNP) | VAF 33/149 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV59179183; called by muse, mutect2, varscan2
- PAM | c.1604G>T p.W535L | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs1244435682, COSV57220054; called by muse, mutect2, varscan2
- PAPPA2 | c.4042C>T p.P1348S | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as COSV62811738; called by muse, mutect2, varscan2
- PAPPA2 | c.5108G>T p.W1703L | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); catalogued as COSV62809045, COSV62811744; called by muse, mutect2, varscan2
- PCDH11X | c.2945C>T p.S982F | Missense Mutation (SNP) | VAF 51/145 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53504429; called by muse, mutect2, varscan2
- PCDHB15 | c.1631A>G p.E544G | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.497); catalogued as rs1554292134, COSV51424280; called by muse, mutect2, varscan2
- PDE1C | c.727C>T p.L243F | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.186); catalogued as COSV58524806; called by muse, varscan2
- PDGFD | c.811A>G p.S271G | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs755849936, COSV100160702, COSV56394207; called by muse, mutect2, varscan2
- PDZD11 | c.137G>C p.R46P | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV52105056, COSV52105271; called by muse, mutect2, varscan2
- PHIP | c.4481T>C p.I1494T | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV51510860; called by muse, mutect2, varscan2
- PKP2 | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.122); catalogued as rs1396519956, COSV50749210; called by muse, mutect2, varscan2
- PLAC1 | c.214C>A p.Q72K | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.495); catalogued as COSV63657248; called by muse, mutect2, varscan2
- PLXND1 | c.5239C>G p.Q1747E | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100139710, COSV60719415; called by muse, mutect2, varscan2
- PPIG | c.807G>T p.Q269H | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.19); catalogued as COSV53646141; called by muse, mutect2, varscan2
- PRAME | c.457C>T p.Q153* | Nonsense Mutation (SNP) | VAF 25/61 reads (41%) | catalogued as rs1031074012, COSV101287265; called by muse, mutect2, varscan2
- PRICKLE3 | c.296G>A p.G99D | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV54297064; called by muse, mutect2, varscan2
- PRNP | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 19/54 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.929); catalogued as COSV65174049; called by muse, mutect2, varscan2
- PROSER3 | c.712C>G p.P238A | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as COSV56555117; called by muse, mutect2, varscan2
- PSMD7 | c.779T>A p.V260E | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV54698656; called by muse, mutect2, varscan2
- PTCD3 | c.1015C>G p.L339V | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54483492; called by muse, mutect2, varscan2
- PTPRG | c.218C>T p.T73M | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.59); catalogued as rs182010071, COSV55662828; called by muse, mutect2, varscan2
- RAG1 | c.2303A>G p.Y768C | Missense Mutation (SNP) | VAF 29/45 reads (64%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55028308; called by muse, mutect2, varscan2
- RALGAPA1 | c.3013C>G p.P1005A | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.048); catalogued as COSV51881094, COSV51896692, COSV99356649; called by muse, mutect2, varscan2
- RELCH | c.890A>G p.N297S | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56892325; called by muse, mutect2, varscan2
- RIC8B | c.808A>T p.T270S | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.51); PolyPhen benign (0.083); catalogued as COSV62697166; called by muse, mutect2, varscan2
- RIT2 | c.524A>G p.H175R | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.608); catalogued as rs1249827726, COSV58677329; called by muse, mutect2, varscan2
- RPF2 | c.527G>T p.R176L | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs150251680, COSV64369933; called by muse, mutect2, varscan2
- RPN2 | c.695A>C p.Q232P | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52909095; called by muse, varscan2
- RTEL1 | c.2033C>T p.S678F | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58891288, COSV58901671; called by muse, mutect2, varscan2
- SERTAD3 | c.355C>T p.L119F | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.71); PolyPhen benign (0.015); catalogued as rs376327614; called by muse, mutect2, varscan2
- SEZ6L2 | c.1361T>C p.L454P (on ENST00000308713 / NM_001114099.3; = p.L384P on NM_012410.4) | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58104247; called by muse, mutect2, varscan2
- SHANK1 | c.212G>A p.S71N | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0.043); catalogued as rs1207754858, COSV53262496; called by muse, mutect2, varscan2
- SLC17A3 | c.469T>C p.Y157H | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57761512; called by muse, mutect2, varscan2
- SLC25A12 | c.1915T>A p.Y639N | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV55537344, COSV99785485; called by muse, mutect2, varscan2
- SLC4A4 | c.390-2A>G p.X130_splice (on ENST00000264485 / NM_001098484.3; = p.X86_splice on NM_003759.4) | Splice Site (SNP) | VAF 20/49 reads (41%) | catalogued as COSV52638244; called by muse, mutect2, varscan2
- SLC6A15 | c.1795T>C p.Y599H | Missense Mutation (SNP) | VAF 53/148 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57029829; called by muse, mutect2, varscan2
- SLIT1 | c.2617C>T p.H873Y | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as rs1313496741, COSV56599352; called by muse, mutect2, varscan2
- SNX8 | c.152C>T p.P51L | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.081); catalogued as COSV56130173; called by muse, mutect2, varscan2
- SOX1 | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs1287341539, COSV58380581; called by muse, mutect2, varscan2
- SPPL2B | c.1497G>A p.W499* | Nonsense Mutation (SNP) | VAF 26/57 reads (46%) | catalogued as rs1464928626, COSV71765668; called by muse, mutect2, varscan2
- SULT2A1 | c.578G>A p.R193K | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as COSV55764602; called by muse, mutect2, varscan2
- TAS2R60 | c.639G>A p.M213I | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT tolerated (0.46); PolyPhen benign (0.018); catalogued as rs141559059, COSV60330146; called by muse, mutect2, varscan2
- TBX5 | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100091069, COSV59865398; called by muse, mutect2, varscan2
- THOC2 | c.4336C>T p.P1446S | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.015); catalogued as COSV55555652; called by muse, mutect2, varscan2
- TMEM255A | c.168T>G p.N56K | Missense Mutation (SNP) | VAF 54/133 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59031424; called by muse, mutect2, varscan2
- TMEM63B | c.1293G>C p.W431C | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV52476799; called by muse, mutect2, varscan2
- TP53BP2 | c.2830G>A p.E944K (on ENST00000343537 / NM_001031685.3; = p.E815K on NM_005426.2) | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100636528, COSV59073019; called by muse, mutect2, varscan2
- TRA2B | c.624G>A p.M208I | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.183); catalogued as COSV52026388; called by muse, mutect2, varscan2
- TRIM15 | c.109C>T p.R37W | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs1475698216, COSV64990422; called by muse, mutect2, varscan2
- TRPA1 | c.3352G>C p.E1118Q | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); catalogued as COSV51574340; called by muse, mutect2, varscan2
- TSKS | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.003); catalogued as COSV55879326; called by muse, mutect2, varscan2
- TTN | c.73289T>A p.V24430D (on ENST00000591111; = p.V17006D on NM_003319.4) | Missense Mutation (SNP) | VAF 33/124 reads (27%) | PolyPhen probably damaging (0.998); catalogued as COSV60352138; called by muse, mutect2, varscan2
- TTN | c.8902C>T p.P2968S (on ENST00000591111; = p.P2922S on NM_003319.4) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | PolyPhen probably damaging (0.998); catalogued as rs773875566, COSV100631490, COSV60107027; ClinVar: uncertain significance; called by mutect2, varscan2
- TUBD1 | c.778A>T p.M260L | Missense Mutation (SNP) | VAF 73/97 reads (75%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV57874544; called by muse, mutect2, varscan2
- VARS1 | c.2635G>A p.G879R | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63305150; called by muse, mutect2, varscan2
- VN1R2 | c.1188A>G p.*396Wext*? | Nonstop Mutation (SNP) | VAF 42/92 reads (46%) | catalogued as COSV100448202; called by muse, mutect2, varscan2
- VRK1 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 39/143 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV53711570; called by muse, mutect2, varscan2
- VRTN | c.1169C>T p.S390F | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0.125); catalogued as COSV56443678; called by muse, mutect2, varscan2
- ZFHX4 | c.3065G>A p.R1022K | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as rs752619547, COSV51496482; called by muse, mutect2, varscan2
- ZFP3 | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 52/63 reads (83%) | SIFT tolerated (0.27); PolyPhen benign (0.054); catalogued as COSV59584222; called by muse, mutect2, varscan2
- ZNF229 | c.2374G>A p.G792R | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV52164973; called by muse, mutect2, varscan2
- ZNF253 | c.1310C>G p.S437* | Nonsense Mutation (SNP) | VAF 9/80 reads (11%) | catalogued as rs775306402, COSV63039614; called by muse, mutect2, varscan2
- ZNF292 | c.1019A>G p.E340G | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1446452306, COSV60546750; called by muse, mutect2, varscan2
- ZNF676 | c.316T>C p.C106R (on ENST00000650058; = p.C74R on NM_001001411.3) | Missense Mutation (SNP) | VAF 50/90 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV68095004; called by muse, mutect2, varscan2
- CDKN1A | c.35del p.P12Hfs*19 | Frame Shift Del (DEL) | VAF 9/23 reads (39%) | called by mutect2, pindel, varscan2
- CFHR3 | c.668_670del p.S223del | In Frame Del (DEL) | VAF 42/177 reads (24%) | called by pindel, varscan2
- CNOT10 | c.1213_1215+1del | Frame Shift Del (DEL) | VAF 24/33 reads (73%) | called by mutect2, pindel, varscan2
- DDX52 | c.1742A>T p.Q581L | Missense Mutation (SNP) | VAF 39/54 reads (72%) | SIFT tolerated (0.06); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ELF3 | c.135dup p.N46Qfs*46 | Frame Shift Ins (INS) | VAF 15/61 reads (25%) | called by mutect2, pindel, varscan2
- HEPACAM | c.716G>A p.S239N | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by muse, mutect2
- PKHD1L1 | c.8306del p.G2769Vfs*27 | Frame Shift Del (DEL) | VAF 17/63 reads (27%) | called by mutect2, pindel, varscan2
- A2M | c.2316G>A p.L772= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV59392507; called by muse, mutect2, varscan2
- ACTR10 | c.315C>T p.L105= | Silent (SNP) | VAF 37/119 reads (31%) | catalogued as rs372194628; called by muse, mutect2, varscan2
- ADAMTS19 | c.1125G>A p.Q375= | Silent (SNP) | VAF 32/102 reads (31%) | catalogued as rs1430958749, COSV50798669; called by muse, mutect2, varscan2
- BCOR | c.2712T>C p.P904= | Silent (SNP) | VAF 24/56 reads (43%) | catalogued as COSV60718484; called by muse, mutect2, varscan2
- CEP128 | c.1398G>A p.Q466= | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as rs775746429, COSV55390708; called by muse, mutect2, varscan2
- COL14A1 | c.3135T>C p.D1045= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as rs748144078, COSV52868856; called by muse, mutect2, varscan2
- CPAMD8 | c.2778C>T p.S926= (on ENST00000651564; = p.S879= on NM_015692.5) | Silent (SNP) | VAF 39/117 reads (33%) | catalogued as rs768363463, COSV71596526; called by muse, mutect2, varscan2
- CTSG | c.66C>T p.I22= | Silent (SNP) | VAF 23/75 reads (31%) | catalogued as rs1419309919, COSV53534645, COSV53534887; called by muse, mutect2, varscan2
- CXCL11 | c.225A>T p.L75= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as COSV60666657; called by muse, mutect2, varscan2
- DIP2A | c.4203C>T p.Y1401= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV59486852; called by muse, mutect2, varscan2
- DRD5 | c.1200C>A p.I400= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs866493427, COSV58580341, COSV58580483; called by muse, mutect2, varscan2
- DSCAML1 | c.1605C>T p.P535= (on ENST00000321322; = p.P475= on NM_020693.4) | Silent (SNP) | VAF 25/85 reads (29%) | catalogued as COSV58381355, COSV58402792; called by muse, mutect2, varscan2
- DYNC1I1 | c.369C>A p.T123= | Silent (SNP) | VAF 55/194 reads (28%) | catalogued as COSV61471512; called by muse, mutect2, varscan2
- ERN2 | c.2409G>A p.E803= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs1166487832, COSV55624315; called by muse, mutect2, varscan2
- EYA4 | c.1272T>C p.D424= (on ENST00000531901 / NM_001301013.1; = p.D418= on NM_004100.5) | Silent (SNP) | VAF 26/82 reads (32%) | catalogued as COSV62060851; called by muse, mutect2, varscan2
- F8 | c.3834T>C p.N1278= | Silent (SNP) | VAF 26/80 reads (33%) | catalogued as COSV64278770; called by muse, mutect2, varscan2
- FAXDC2 | c.891T>C p.H297= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV58174018; called by muse, mutect2, varscan2
- FLI1 | c.573C>T p.L191= | Silent (SNP) | VAF 35/83 reads (42%) | catalogued as rs1408294515, COSV55644986; called by muse, mutect2, varscan2
- FLNA | c.6490C>T p.L2164= (on ENST00000369850 / NM_001110556.2; = p.L2156= on NM_001456.3) | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as COSV61051716; called by muse, mutect2, varscan2
- GABRR2 | c.282G>T p.V94= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV101299046; called by muse, mutect2
- GDPD4 | c.1446T>C p.F482= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV60023092; called by muse, mutect2, varscan2
- GFOD2 | c.471G>A p.L157= | Silent (SNP) | VAF 14/28 reads (50%) | catalogued as rs1254520390, COSV52059873; called by muse, mutect2, varscan2
- GOLGA3 | c.3294G>A p.K1098= | Silent (SNP) | VAF 40/122 reads (33%) | catalogued as COSV52643529; called by muse, mutect2, varscan2
- HSD17B6 | c.498G>A p.L166= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as rs1426862355, COSV59108721; called by muse, mutect2, varscan2
- IDH2 | c.753G>A p.K251= | Silent (SNP) | VAF 30/89 reads (34%) | catalogued as rs1458791406, COSV57482645; called by muse, mutect2, varscan2
- IGKV1-17 | c.27C>A p.L9= | Silent (SNP) | VAF 59/269 reads (22%) | called by muse, mutect2, varscan2
- IGSF1 | c.2367C>A p.V789= | Silent (SNP) | VAF 28/91 reads (31%) | catalogued as COSV63840357; called by muse, mutect2, varscan2
- IGSF1 | c.1323C>T p.C441= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as rs375323362, COSV100812325, COSV63840366; called by muse, mutect2, varscan2
- JRK | c.1575G>A p.Q525= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs1554635123, COSV101401170; called by muse, mutect2, varscan2
- KLHL4 | c.975T>A p.A325= | Silent (SNP) | VAF 26/63 reads (41%) | catalogued as COSV100909071, COSV64147933; called by muse, mutect2, varscan2
- LDB2 | c.90C>T p.Y30= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as COSV58782822; called by muse, mutect2, varscan2
- LILRB4 | c.693C>T p.S231= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs754810930, COSV54404654; called by muse, mutect2, varscan2
- LINGO2 | c.813C>T p.H271= | Silent (SNP) | VAF 27/68 reads (40%) | catalogued as rs1187458983, COSV58064455; called by muse, mutect2, varscan2
- LMBRD2 | c.1110T>C p.N370= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV56952834; called by muse, mutect2, varscan2
- MAGEB16 | c.418T>C p.L140= | Silent (SNP) | VAF 27/43 reads (63%) | catalogued as COSV67874602; called by muse, mutect2, varscan2
- MAGEE1 | c.381T>C p.S127= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as COSV63912114; called by muse, mutect2, varscan2
- MTCP1 | c.90G>T p.V30= | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as COSV62900703; called by muse, mutect2, varscan2
- MTMR3 | c.1971A>G p.G657= | Silent (SNP) | VAF 28/77 reads (36%) | catalogued as COSV60308831; called by muse, mutect2, varscan2
- MUC17 | c.12624C>T p.S4208= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as rs1239561930, COSV60303455; called by muse, mutect2, varscan2
- MYH10 | c.1197C>T p.P399= | Silent (SNP) | VAF 36/55 reads (65%) | catalogued as COSV52611381; called by muse, mutect2, varscan2
- MYO10 | c.867G>A p.L289= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV72454759; called by muse, mutect2, varscan2
- MYO7A | c.4734C>T p.D1578= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs747155741, COSV68687070; called by muse, mutect2, varscan2
- NID1 | c.939C>T p.F313= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as COSV51629039; called by muse, mutect2, varscan2
- NLRP13 | c.1398A>T p.T466= | Silent (SNP) | VAF 48/92 reads (52%) | catalogued as COSV61624089; called by muse, mutect2, varscan2
- OR2C3 | c.447C>T p.S149= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs1448418682, COSV100825799; called by muse, mutect2, varscan2
- PCDHA4 | c.1773G>A p.V591= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as rs1554124917, COSV63544564, COSV63546146; called by muse, mutect2, varscan2
- PCDHAC2 | c.2016C>T p.A672= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as rs1256152245, COSV53862940; called by muse, mutect2, varscan2
- PCDHB8 | c.462T>A p.P154= | Silent (SNP) | VAF 30/169 reads (18%) | catalogued as COSV50816844; called by muse, mutect2, varscan2
- PDGFRA | c.2823C>G p.P941= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as COSV57274212; called by muse, mutect2, varscan2
- PELI2 | c.675G>A p.S225= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as rs781707433, COSV50710212; called by muse, mutect2, varscan2
- PHACTR3 | c.1512C>T p.Y504= | Silent (SNP) | VAF 20/38 reads (53%) | catalogued as rs1373651322, COSV63025035; called by muse, mutect2, varscan2
- RPN2 | c.696G>A p.Q232= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as COSV52909105; called by muse, mutect2, varscan2
- RYR1 | c.2592C>T p.P864= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs199541173, COSV62110930; called by muse, mutect2, varscan2
- SHANK1 | c.831C>T p.D277= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as rs768674371, COSV53262475; called by muse, mutect2, varscan2
- SLC6A5 | c.483G>A p.L161= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as COSV54232526; called by muse, mutect2, varscan2
- SLITRK4 | c.549G>T p.L183= | Silent (SNP) | VAF 34/113 reads (30%) | catalogued as COSV62026131; called by muse, mutect2, varscan2
- SPATA21 | c.726G>A p.Q242= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as rs1354707891, COSV59187756, COSV59188834; called by muse, mutect2, varscan2
- STS | c.1653G>A p.K551= | Silent (SNP) | VAF 20/41 reads (49%) | catalogued as rs1261809444, COSV54272033; called by muse, mutect2, varscan2
- TENM4 | c.3762C>A p.I1254= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as COSV53671395; called by muse, mutect2, varscan2
- TEP1 | c.4317G>A p.R1439= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV53000273; called by muse, mutect2, varscan2
- TEX15 | c.6876G>A p.T2292= (on ENST00000256246; = p.T2675= on NM_001350162.2) | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as rs1460664828, COSV56343622; called by muse, mutect2, varscan2
- THSD7B | c.219G>T p.G73= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as COSV55738113; called by muse, mutect2, varscan2
- TRIM56 | c.1635G>A p.P545= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as rs373662821; called by muse, mutect2, varscan2
- TTN | c.97173T>C p.Y32391= (on ENST00000591111; = p.Y24967= on NM_003319.4) | Silent (SNP) | VAF 25/85 reads (29%) | catalogued as rs771155641, COSV60352102; called by muse, mutect2, varscan2
- XIRP2 | c.1462T>C p.L488= (on ENST00000628543; = p.L663= on NM_152381.6) | Silent (SNP) | VAF 28/63 reads (44%) | catalogued as rs370115866; called by muse, mutect2, varscan2
- ZDHHC9 | c.204C>A p.I68= | Silent (SNP) | VAF 26/62 reads (42%) | catalogued as COSV64097393; called by muse, mutect2, varscan2
- ZKSCAN2 | c.372G>A p.E124= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as COSV60158779; called by muse, mutect2, varscan2
- ZNF16 | c.1752A>T p.R584= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as COSV52765652; called by muse, mutect2, varscan2
- ZNF385C | c.1350C>A p.I450= | Silent (SNP) | VAF 26/39 reads (67%) | catalogued as COSV56918427; called by muse, mutect2, varscan2
- ZNF512B | c.891C>T p.S297= | Silent (SNP) | VAF 126/244 reads (52%) | catalogued as rs931558517, COSV53878737; called by muse, mutect2, varscan2
- ZNF808 | c.1156C>T p.L386= | Silent (SNP) | VAF 28/155 reads (18%) | catalogued as rs376130524; called by muse, mutect2, varscan2
- ZXDA | c.924C>T p.G308= | Silent (SNP) | VAF 11/17 reads (65%) | catalogued as COSV100699475; called by muse, mutect2, varscan2
- ACBD4 | chr17:45143529 C>A | 3'Flank (SNP) | VAF 16/75 reads (21%) | catalogued as COSV100203609; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73852038 C>A | 3'Flank (SNP) | VAF 9/19 reads (47%) | called by muse, mutect2, varscan2
- CFAP47 | c.2844+53G>T | Intron (SNP) | VAF 8/26 reads (31%) | catalogued as COSV52892030; called by muse, mutect2, varscan2
- HLA-DRB9 | n.181C>T | RNA (SNP) | VAF 30/81 reads (37%) | called by muse, mutect2, varscan2
- IPO13 | c.*2G>A | 3'UTR (SNP) | VAF 8/20 reads (40%) | catalogued as COSV99664770; called by muse, mutect2, varscan2
- PRUNE2 | c.756+22T>C | Intron (SNP) | VAF 17/40 reads (43%) | catalogued as rs1355454752; called by muse, mutect2, varscan2
- XIRP2 | c.*770A>G | 3'UTR (SNP) | VAF 20/56 reads (36%) | catalogued as COSV54734552; called by muse, mutect2, varscan2
- ZNF99 | c.*273T>C | 3'UTR (SNP) | VAF 35/151 reads (23%) | catalogued as COSV68056784; called by muse, mutect2, varscan2
